Surgical pathology report (de-identified scan), TCGA case TCGA-WN-AB4C, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of Kansas, specimen TCGA-WN-AB4C-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

NAME:	SURG PATH #:
MR #:	SPECIMEN CLASS:
BILLING #:	ALT ID #:
LOCATION:	DATE OF PROCEDURE:
AGE:	DATE RECEIVED:
DOB:	TIME RECEIVED:
PHYSICIAN:	DATE OF REPORT:
COPY TO:	DATE OF PRINTING:

Material Received:

A: right kidney mass

*ICD-O-3
Carcinoma, papillary renal cell 8260/3
Site: @ Kidney NOS C64.9
p 5/30/14*

History:

-year-old female with right renal mass.

Final Diagnosis:

A. Kidney, "right kidney mass", partial nephrectomy:
Papillary renal cell carcinoma (2.6 cm), Fuhrman nuclear grade 3. See comment.

Comment:

Kidney

Specimen Type: Partial nephrectomy

Laterality: Right

Tumor Site: Cannot be determined

Focality: Unifocal

Tumor Size (largest tumor if multiple): 2.6 x 2.0 x 2.0 cm

Histologic Type: Papillary renal cell carcinoma

Histologic (Fuhrman) Grade: G3: Nuclei very irregular, nucleoli large and prominent

Macroscopic Extent of Tumor: Confined to the kidney

Surgical Margins: Margin uninvolved by invasive carcinoma (focally the parenchymal resection is less than 0.5 mm from the tumor)

Adrenal Gland: Not applicable

Large vessel invasion (renal vein, vena cava): Not applicable

Microvascular invasion: Not identified

Lymph Nodes:

Number Examined: None

Number Involved: Not applicable

Additional Pathologic Findings: None

Gross Picture Taken: No

Pathologic Staging: pT1aNX

Renal Cell Carcinoma

Primary Tumor (pT)

pT1a: Tumor 4 cm or less in greatest dimension, limited to the kidney

Regional Lymph Nodes (pN)

pNX: Cannot be assessed

MR #:

Page 1 of 1

Date of Printing:

SURGICAL PATHOLOGY REPORT

Order Number:

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

Distant Metastasis (pM)

pMX: Cannot be assessed

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

Pursuant to the _____ this case has been concurrently reviewed by the following pathologist: _____ who agrees with the above diagnosis.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Electronically Signed Out By

Interpreted by:

Gross Description:

A. Received fresh labeled with the patient's name and "right kidney mass" is a 2.8 x 2.2 x 2.1 cm partial nephrectomy specimen. The parenchymal resection margin is pink-black. The specimen is serially sectioned to reveal a 2.6 x 2.0 x 2.0 cm white-tan soft well-circumscribed mass. Grossly the mass is less than 1 mm from the inked resection margin. Grossly the uninvolved renal parenchyma is tan-brown and unremarkable. Representative section of the mass to the resection margin are submitted in cassette A1FS. A piece of the tumor is submitted to tissue bank. The remainder of the specimen is entirely submitted in cassettes A2-A6.

Intraoperative Consultation:

A1FS, kidney, "right kidney mass":

Papillary renal cell carcinoma; the parenchymal resection margin is negative (less than 0.5 mm from the tumor).

Date of Printing:

MR #:

SURGICAL PATHOLOGY REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file f391a0b1-060e-40ab-a862-65330e464230 (TCGA-WN-AB4C.10EB313B-8BE4-4C5B-B3BF-97646B251784.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).